Somatic mutation profile of tumor specimen TCGA-DX-AB2O-01A (aliquot TCGA-DX-AB2O-01A-12D-A38Z-09) from TCGA case TCGA-DX-AB2O, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.7 years (28,757 days).
Specimen TCGA-DX-AB2O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0e96c0-cf66-445d-9766-4b718c64e1ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2O-10A (Blood Derived Normal), aliquot TCGA-DX-AB2O-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b19095fa-ee42-487c-a2bb-37c56fa093e5

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 34, Silent 17, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRA | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100357423; called by muse, mutect2, varscan2
- AQP4 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs886513761, COSV101270465; called by muse, mutect2, varscan2
- AXL | c.1831G>A p.E611K (on ENST00000301178 / NM_021913.5; = p.E602K on NM_001699.6) | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV99995678; called by muse, mutect2, varscan2
- BRINP2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs768723571, COSV64177620; called by muse, mutect2
- C18orf54 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199598871, COSV100266215; called by muse, mutect2, varscan2
- CARMIL3 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1417718967, COSV100549035, COSV57728396; called by muse, mutect2, varscan2
- CSPP1 | c.2496G>T p.E832D (on ENST00000676605; = p.E791D on NM_024790.6) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99137925; called by muse, mutect2
- DHCR7 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100831663; called by muse, mutect2, varscan2
- DNAH11 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100176071; called by muse, mutect2, varscan2
- ENAM | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs752376600, COSV101252837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENGASE | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100285594; called by muse, mutect2, varscan2
- FLNC | c.5434C>G p.P1812A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV100367446; called by muse, mutect2, varscan2
- GOLGA1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV101001972; called by muse, mutect2, varscan2
- GPR37 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100390439; called by muse, mutect2, varscan2
- HASPIN | c.1476A>T p.E492D | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99560073; called by muse, mutect2, varscan2
- HMGB3 | c.353T>G p.I118S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV100308376; called by muse, mutect2, varscan2
- ITLN1 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100406103; called by muse, mutect2
- KATNIP | c.3925G>A p.G1309S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99849317; called by muse, mutect2, varscan2
- KLK8 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99143861; called by muse, mutect2, varscan2
- MGAT5B | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs780552431, COSV100046966, COSV56931596; called by muse, mutect2, varscan2
- MUC17 | c.6347G>T p.S2116I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV100071024; called by muse, mutect2, varscan2
- NOTCH1 | c.3664G>A p.V1222M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs112900950, COSV53084637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAX6 | c.1235C>G p.P412R | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV99569956; called by muse, mutect2
- PCNT | c.4655C>T p.S1552L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs915028258, COSV100854920; called by muse, mutect2, varscan2
- PKD2L1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs1382069440, COSV100559225; called by muse, mutect2, varscan2
- POC1B | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.601); catalogued as COSV100543966, COSV57964303; called by muse, mutect2, varscan2
- POC1B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100543969; called by muse, mutect2, varscan2
- PRPF8 | c.3379G>A p.G1127S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100516975; called by muse, mutect2, varscan2
- RECQL5 | c.2501C>A p.P834H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV100511468, COSV58642433; called by muse, mutect2
- SPATA31E1 | c.3073C>A p.Q1025K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as COSV100349689, COSV57793480; called by muse, mutect2, varscan2
- STK33 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173502; called by muse, mutect2, varscan2
- TSR1 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750076259, COSV56784471; called by muse, mutect2, varscan2
- ZAP70 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs150631046; called by muse, mutect2, varscan2
- ZNF331 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99466688; called by muse, mutect2, varscan2
- ZNF705A | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as rs755206074, COSV100828256, COSV63732918; called by muse, mutect2, varscan2
- DNMT3A | c.1066_1073del p.Q356Vfs*34 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- SPTAN1 | c.2450_2470del p.I817_L823del | In Frame Del (DEL) | VAF 14/57 reads (25%) | called by pindel, varscan2*
- TRIM46 | c.957del p.L320Wfs*99 | Frame Shift Del (DEL) | VAF 26/53 reads (49%) | called by mutect2, pindel, varscan2
- CYBB | c.168T>C p.P56= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101059662; called by muse, mutect2, varscan2
- FBH1 | c.3081G>A p.V1027= (on ENST00000362091 / NM_178150.3; = p.V1078= on NM_032807.4) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100758543; called by muse, mutect2, varscan2
- GATA2 | c.1383C>G p.P461= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100350723, COSV62006276; called by muse, mutect2, varscan2
- GATAD2A | c.1473C>T p.T491= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs766602148, COSV99389423; called by muse, mutect2, varscan2
- LRRC46 | c.729C>T p.P243= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- OR10J3 | c.756C>T p.H252= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs532378990, COSV100171543; called by muse, mutect2
- OSBP2 | c.1014C>T p.D338= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs149092338, COSV60243466; called by muse, mutect2, varscan2
- PCDHB4 | c.1806G>A p.S602= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1554274629, COSV52027397; called by muse, mutect2, varscan2
- PISD | c.1068G>A p.T356= (on ENST00000439502 / NM_001326412.1; = p.T322= on NM_014338.3) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs376765197; called by muse, mutect2, varscan2
- SHOX2 | c.501C>T p.A167= (on ENST00000441443 / NM_006884.3; = p.A191= on NM_003030.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1229692077, COSV101273723; called by muse, mutect2, varscan2
- SOX8 | c.531G>A p.K177= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99559068; called by muse, mutect2, varscan2
- SPHKAP | c.186G>A p.Q62= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100763548; called by muse, mutect2, varscan2
- ST18 | c.1581A>G p.P527= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs1286390102, COSV99387616; called by muse, mutect2, varscan2
- TMEM237 | c.1226A>G p.*409= (on ENST00000409883 / NM_001044385.3; = p.*401= on NM_152388.4) | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV99635396; called by muse, mutect2, varscan2
- VMO1 | c.522C>T p.C174= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54497029; called by muse, mutect2, varscan2
- VPS35L | c.1962G>A p.L654= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99219200; called by muse, mutect2, varscan2
